Surgical pathology report (de-identified scan), TCGA case TCGA-W2-A7HE, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Medical College of Wisconsin, specimen TCGA-W2-A7HE-01A (Primary Tumor).

[page 1 of 2]
Results History

SURG PATH FINAL REPORT

Entry Information

Entry Date and Time

Lab Status
Final result

Entered by

Component Results

SURG PATH FINAL REPORT:

ICD-0-3

Pheochromocytoma NOS
8700/0
Site R Adrenal gland NOS
C74.9
JW 9/4/13

Accession #:

Specimen:

Date of Procedure:

Performing Clinician:

A. Right adrenal

Clinical Notes:

Fresh tissue saved for tissue bank. Pre-op
diagnosis: Right adrenal pheochromocytoma.

Diagnosis:

A. Right adrenal, adrenalectomy:
- Pheochromocytoma.

Note: there is no evidence of capsular or vascular
invasion or necrosis. The tumor appears to be
confined to the adrenal.

(Electronically signed by)

Verified:

Gross:

A. The specimen is labeled "right adrenal." Received fresh is a 19 gram portion of adrenal with adherent fibroadipose tissue. The overall dimensions of the specimen are 10.0 x 3.0 x 1.1 cm. The adrenal gland itself measures 5.5 x 2.2 x 1.8 cm. The specimen has been previously incised revealing a 1.6 x 1.6 x 1.1 cm mass which is tan-white to pink. At the periphery of the mass is a thin rim of orange cortex. There is a small amount of grossly normal adrenal tissue at one end of the specimen with a yellow-white cortex measuring approximately 0.1 cm and a brown medulla measuring approximately 0.2 cm. The specimen is serially sectioned in the plane of previous sectioning. There is a small disrupted portion of adrenal received separately in the same container measuring 2.5 x 1.0 x 1.5 cm. A portion of tissue has been saved for Representative sections of the specimen are submitted as follows:

[page 2 of 2]
Cassette Designation:

A1-4 Adrenal gland and nodule
A5 Disrupted portion of adrenal
gland, received in the same container

Accession #:

Microscopic:

A histological examination has been performed.

Administrative Notes:

CPT:

No charge codes are associated with this case.

Entry Information

Entry Date and Time	Lab Status	Entered by
	In process	

Criteria	hw 8/29/13	Yes	No
Diagnostic Discrepancy			///
HPA Discrepancy			///

Source: NCI Genomic Data Commons file 88f7ce6d-f781-4724-b56d-9853337bea9c (TCGA-W2-A7HE.97EED12B-1475-4FD8-9987-6093C6F00546.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).